Gene-level copy-number profile of tumor specimen TCGA-XE-AANS-01A from TCGA case TCGA-XE-AANS, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 30.5 years (11,151 days).
Specimen TCGA-XE-AANS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f7bd5ad4-91c6-43a8-a33d-c24c7c7a76b5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AANS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/8722fbf2-0ccb-4f4d-947d-bfbd19bf56f5

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 529; copy number 2: 38; copy number 3: 3,608; copy number 4: 16,864; copy number 5: 11,823; copy number 6: 20,003; copy number 7: 2,195; copy number 8: 1,923; copy number 9: 64; copy number 10: 1,034; copy number 12: 14; copy number 13: 13; copy number 14: 29; copy number 15: 771.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 813 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:166,856–33,455,452, 813 genes, copy number 13–15 (within-gene range 10–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
